Somatic mutation profile of tumor specimen TCGA-63-A5MP-01A (aliquot TCGA-63-A5MP-01A-11D-A26M-08) from TCGA case TCGA-63-A5MP, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-A5MP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee6000eb-1c59-49d4-9156-143d5e161d7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MP-10A (Blood Derived Normal), aliquot TCGA-63-A5MP-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28845dc6-936b-477f-a9ec-8dd52de4691e

The open-access MAF lists 212 somatic variants for this specimen: 156 protein-altering or splice-affecting, 52 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 52, Nonsense Mutation 12, Frame Shift Del 7, Splice Site 4, Intron 2, Frame Shift Ins 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.6232C>T p.R2078* | Nonsense Mutation (SNP) | VAF 7/71 reads (10%) | catalogued as rs199422168, CM095684, COSV54125033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1456262672, COSV99566581; called by muse, mutect2, varscan2
- ABCA8 | c.1518T>G p.I506M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99286755; called by muse, mutect2, varscan2
- ABLIM1 | c.21G>A p.M7I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV100986622; called by muse, mutect2, varscan2
- AC131160.1 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100226362; called by muse, mutect2, varscan2
- ADAMTS12 | c.1886C>A p.P629Q | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV61285676; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1736C>A p.T579K | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV54471102, COSV99720931; called by muse, mutect2, varscan2
- ADCY1 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52030101; called by muse, mutect2
- ADGRB3 | c.2860G>C p.A954P | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99486716; called by muse, mutect2, varscan2
- ADGRD1 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.317); catalogued as COSV99896813; called by muse, varscan2
- ADGRL3 | c.2426T>G p.I809S (on ENST00000506720 / NM_001322402.2; = p.I741S on NM_015236.6) | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV101547378; called by muse, mutect2, varscan2
- AFAP1 | c.844A>T p.S282C | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100632092; called by muse, mutect2, varscan2
- ANGPTL2 | c.1452G>A p.M484I | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV99402493; called by muse, mutect2, varscan2
- ARHGAP18 | c.1778T>C p.I593T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100936347; called by muse, mutect2
- ASTN1 | c.3067C>T p.Q1023* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as COSV100707644; called by muse, mutect2, varscan2
- ASXL3 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99324027, COSV99326364; called by muse, mutect2
- ATP6V1E2 | c.164A>T p.E55V | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as COSV100120816; called by muse, mutect2
- CBR1 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99289599; called by muse, mutect2, varscan2
- CCDC105 | c.141G>T p.W47C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV99480103; called by muse, mutect2
- CDH12 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66427479; called by muse, mutect2, varscan2
- CDK14 | c.948-2A>T p.X316_splice (on ENST00000380050 / NM_001287135.2; = p.X298_splice on NM_012395.3) | Splice Site (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99726756; called by muse, mutect2
- CFAP91 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs141246031; called by muse, mutect2
- CIAO2A | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 9/100 reads (9%) | catalogued as rs1467688371, COSV55538342; called by muse, mutect2
- CKAP5 | c.748G>T p.G250* | Nonsense Mutation (SNP) | VAF 39/161 reads (24%) | catalogued as COSV100371375; called by muse, mutect2, varscan2
- CLTCL1 | c.2392A>G p.R798G | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs782614572, COSV99595776; called by muse, mutect2
- CPAMD8 | c.604A>T p.N202Y (on ENST00000651564; = p.N155Y on NM_015692.5) | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV99359770; called by muse, mutect2, varscan2
- CREB3L2 | c.803A>G p.E268G | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100382261; called by muse, mutect2, varscan2
- CWH43 | c.1784C>A p.T595N | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV99894009; called by muse, mutect2, varscan2
- CYP7A1 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100052622; called by muse, mutect2
- DEF6 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100359519; called by muse, mutect2, varscan2
- DGAT2 | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99929976; called by muse, mutect2, varscan2
- DGKI | c.2062C>G p.P688A | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.275); catalogued as COSV99935948, COSV99937040; called by muse, mutect2, varscan2
- DIO3 | c.325T>G p.C109G | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100832254; called by muse, mutect2, varscan2
- DMRTA2 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV101288902; called by muse, mutect2
- DMXL1 | c.181G>T p.G61* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100224892; called by muse, mutect2, varscan2
- DNAH5 | c.13043G>A p.G4348E | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); catalogued as COSV99453648; called by muse, mutect2, varscan2
- DYNC1I1 | c.1657G>C p.G553R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100269173; called by muse, mutect2
- ENPP7 | c.1196C>G p.P399R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100093670; called by muse, mutect2, varscan2
- EPHA6 | c.964T>A p.S322T | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.737); catalogued as COSV101066084; called by muse, mutect2
- EPM2A | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62296224; called by muse, mutect2, varscan2
- FAM117B | c.1000A>T p.I334F | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100287883; called by muse, mutect2, varscan2
- FBXL7 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.088); catalogued as COSV61645946; called by muse, mutect2, varscan2
- FLNC | c.5002G>A p.V1668M | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100368673; called by muse, mutect2, varscan2
- FRS3 | c.403del p.Q135Sfs*6 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as rs751014865, COSV99442896; called by mutect2, pindel, varscan2
- FTHL17 | c.89A>G p.Y30C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as rs1204032342, COSV100784396, COSV63267696; called by muse, mutect2, varscan2
- GABRA6 | c.1311G>T p.W437C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50882370, COSV50892323; called by muse, mutect2, varscan2
- GIMAP7 | c.96A>T p.E32D | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100543773, COSV57958644; called by muse, mutect2, varscan2
- GLP2R | c.533T>G p.L178W | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99302421; called by muse, mutect2, varscan2
- GLRA2 | c.314C>A p.S105* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99491577; called by muse, mutect2, varscan2
- GPT | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777370445, COSV52952376; called by muse, mutect2, varscan2
- GRM2 | c.2527A>C p.S843R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV99623121; called by muse, mutect2, varscan2
- GRM6 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99179880; called by muse, mutect2, varscan2
- GRXCR1 | c.370A>G p.T124A | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV101295750; called by muse, mutect2, varscan2
- H3C13 | c.307G>C p.G103R | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs1305168156, COSV100516169; called by muse, mutect2, varscan2
- HEPH | c.1340T>C p.L447S (on ENST00000343002; = p.L180S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV100295619; called by muse, mutect2, varscan2
- HOXD9 | c.926A>G p.Y309C | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99982319; called by muse, mutect2, varscan2
- HTRA4 | c.1072G>T p.V358F | Missense Mutation (SNP) | VAF 96/174 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV100205924; called by muse, mutect2, varscan2
- IRS4 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV100929561, COSV100929702; called by mutect2, varscan2
- KALRN | c.3572T>C p.L1191P | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99567055; called by muse, mutect2, varscan2
- KANK4 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100587683, COSV62987102; called by mutect2, varscan2
- KCNQ3 | c.795G>T p.W265C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101196397; called by muse, mutect2, varscan2
- KCNQ5 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100572979, COSV59667758; called by muse, mutect2, varscan2
- KDM7A | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99135075; called by muse, mutect2, varscan2
- KMT2A | c.11357G>A p.R3786H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555052977, COSV63290561; called by muse, mutect2, varscan2
- KMT2D | c.16222G>A p.G5408S | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99985457; called by muse, mutect2, varscan2
- MAP7D2 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.844); catalogued as rs1377288985, COSV101107528; called by muse, mutect2, varscan2
- MARS2 | c.1671C>A p.F557L | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99986687; called by muse, mutect2, varscan2
- MAST3 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV53225571; called by muse, mutect2, varscan2
- MCMBP | c.565A>G p.R189G | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100750165; called by muse, mutect2, varscan2
- MDN1 | c.8394G>T p.L2798F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV101021795; called by muse, mutect2
- MKI67 | c.4765G>A p.A1589T | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.433); catalogued as rs1291232270, COSV100896951; called by muse, varscan2
- MKRN2 | c.1114-1G>C p.X372_splice | Splice Site (SNP) | VAF 68/216 reads (31%) | catalogued as COSV99313330; called by muse, mutect2, varscan2
- MROH2B | c.919G>C p.A307P | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV101270899, COSV68187646; called by muse, mutect2, varscan2
- MUC16 | c.6687G>T p.L2229F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV101201409; called by muse, mutect2, varscan2
- MXRA8 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100492100; called by muse, mutect2
- NCOA6 | c.2432A>G p.D811G | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV62868088; called by muse, mutect2
- NECTIN1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as rs772160830, COSV99872587; called by muse, mutect2
- NLGN4X | c.797C>A p.S266Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99323708; called by muse, mutect2, varscan2
- NLRC4 | c.2938G>C p.D980H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.887); catalogued as rs1472895111, COSV50873556, COSV99250071; called by muse, mutect2, varscan2
- NLRP12 | c.433G>C p.A145P | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV60749767; called by muse, mutect2, varscan2
- NOX4 | c.847-1G>A p.X283_splice | Splice Site (SNP) | VAF 9/53 reads (17%) | catalogued as COSV54450704, COSV99631751; called by muse, mutect2, varscan2
- OLFM3 | c.205G>T p.V69F (on ENST00000338858 / NM_001288821.1; = p.V49F on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100130014; called by muse, mutect2, varscan2
- OR2D2 | c.853C>G p.P285A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100203918; called by muse, mutect2, varscan2
- OR2L2 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV100824316, COSV63549348; called by muse, mutect2, varscan2
- OR2T12 | c.455C>A p.A152D | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV58777265; called by muse, mutect2
- OR52B4 | c.547C>A p.H183N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV101281605; called by muse, mutect2, varscan2
- OR6K2 | c.381C>A p.S127R | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100656880, COSV62744159; called by muse, mutect2, varscan2
- OR8H2 | c.602T>G p.I201S | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV100542470; called by muse, mutect2, varscan2
- ORC2 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV99309716, COSV99309726; called by muse, mutect2, varscan2
- P3H2 | c.2026A>T p.R676* | Nonsense Mutation (SNP) | VAF 18/270 reads (7%) | catalogued as COSV100078402; called by muse, mutect2
- PAFAH1B1 | c.1013A>G p.D338G | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV101250450; called by muse, mutect2, varscan2
- PARP8 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.745); catalogued as COSV99892673; called by muse, mutect2, varscan2
- PAXX | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV100860462; called by muse, mutect2, varscan2
- PCMTD2 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99829577; called by muse, mutect2, varscan2
- PEX1 | c.1264C>G p.L422V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV99952349; called by muse, mutect2, varscan2
- PIGO | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV99956930; called by muse, mutect2, varscan2
- PIK3AP1 | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100226183; called by muse, mutect2, varscan2
- PLCL1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780511339, COSV70844244; called by muse, mutect2, varscan2
- PLEKHG1 | c.426C>A p.C142* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100651858, COSV62046393; called by muse, mutect2, varscan2
- PLXNB2 | c.1918G>T p.D640Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.594); catalogued as COSV100834275; called by muse, mutect2, varscan2
- PRKAA2 | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs900530381, COSV100983062; called by muse, mutect2
- PRKACA | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV100432269; called by muse, mutect2, varscan2
- PROM1 | c.683C>A p.T228K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs760619673, COSV101477128; called by muse, mutect2
- PSME4 | c.5404G>C p.V1802L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV101122632, COSV66367495; called by muse, mutect2, varscan2
- PTK7 | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100030574; called by muse, mutect2, varscan2
- PTPRN2 | c.749C>A p.A250D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.296); catalogued as COSV101235288; called by muse, mutect2
- PTPRR | c.1909T>A p.Y637N | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99318651; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs528799264, COSV99242422; called by muse, mutect2, varscan2
- RALYL | c.136G>C p.G46R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101569425, COSV72822133; called by muse, mutect2, varscan2
- RBM26 | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV57398114; called by muse, mutect2, varscan2
- RGS1 | c.26C>A p.P9Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV100817557; called by muse, mutect2, varscan2
- SAFB2 | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as COSV99386053; called by muse, mutect2, varscan2
- SCAP | c.2912G>A p.W971* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99651011; called by muse, mutect2, varscan2
- SCYL2 | c.495G>T p.L165F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100675304; called by mutect2, varscan2
- SEL1L2 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs373425656; called by muse, mutect2, varscan2
- SEL1L2 | c.839T>C p.L280S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53156692, COSV99533870; called by muse, mutect2, varscan2
- SFSWAP | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55522050; called by muse, mutect2, varscan2
- SHANK1 | c.2303A>G p.K768R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV99521942; called by muse, mutect2, varscan2
- SLC25A25 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100895385; called by muse, mutect2, varscan2
- SLC6A19 | c.1536C>A p.D512E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as COSV100443749; called by muse, mutect2, varscan2
- SNTA1 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV99458924; called by muse, mutect2, varscan2
- SOX30 | c.1435C>A p.P479T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.056); catalogued as COSV99398742; called by muse, mutect2, varscan2
- SPO11 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as rs141106732; called by muse, mutect2
- SRBD1 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1430032098, COSV55401625; called by muse, mutect2, varscan2
- SVIL | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.7); catalogued as rs562741034, COSV100881516; called by muse, mutect2, varscan2
- TBX20 | c.127+2T>G p.X43_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as COSV101282419; called by muse, mutect2, varscan2
- TDRD10 | c.557T>A p.L186Q | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV99427638; called by muse, mutect2, varscan2
- TGM4 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.018); catalogued as rs759273340, COSV56093437; called by muse, mutect2, varscan2
- TLR3 | c.2603G>A p.R868K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.923); catalogued as rs962497425, COSV99711177; called by muse, mutect2, varscan2
- TMEM132E | c.1831A>T p.S611C (on ENST00000321639; = p.S701C on NM_001304438.2) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100396736; called by muse, mutect2, varscan2
- TOGARAM2 | c.2714G>A p.R905H | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.209); catalogued as rs1384468325, COSV101091447; called by muse, mutect2, varscan2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TRIOBP | c.2180G>T p.R727L | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV60380755; called by muse, mutect2, varscan2
- TRPA1 | c.83A>C p.D28A | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100085099; called by muse, mutect2, varscan2
- TRPS1 | c.3193G>T p.G1065C (on ENST00000220888 / NM_001330599.2; = p.G1078C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99635333; called by muse, mutect2
- TTN | c.26863A>T p.S8955C (on ENST00000591111; = p.S8028C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | PolyPhen possibly damaging (0.614); catalogued as COSV100627879; called by muse, mutect2
- TTN | c.2361A>G p.I787M (on ENST00000591111; = p.I741M on NM_003319.4) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | PolyPhen possibly damaging (0.487); catalogued as rs866406896, COSV100627881; called by muse, mutect2, varscan2
- TUBA3C | c.1015C>A p.R339S | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.24); catalogued as COSV101313857, COSV101313881; called by muse, mutect2, varscan2
- USP29 | c.431A>G p.Q144R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV99518587; called by muse, mutect2, varscan2
- UTP23 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100561276, COSV59124589; called by muse, mutect2, varscan2
- VPS16 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV100988607; called by muse, mutect2, varscan2
- YLPM1 | c.393A>T p.Q131H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99461190; called by muse, mutect2, varscan2
- YTHDC1 | c.2155C>T p.R719* (on ENST00000344157 / NM_001031732.4; = p.R701* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100704845; called by muse, mutect2, varscan2
- ZFHX4 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV50924910, COSV51486460, COSV99266984; called by muse, mutect2, varscan2
- ZNF384 | c.1288G>T p.A430S (on ENST00000361959; = p.A369S on NM_133476.5) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100158863; called by muse, mutect2, varscan2
- ZNF391 | c.894C>G p.I298M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99772804; called by muse, mutect2, varscan2
- ZNF829 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs368287177, COSV66986284; called by muse, mutect2, varscan2
- ADAM28 | c.2172_2173del p.Q725Rfs*11 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.3031_3041del p.F1011Vfs*28 (on ENST00000506720 / NM_001322402.2; = p.F943Vfs*28 on NM_015236.6) | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- ARID1A | c.6193dup p.A2065Gfs*34 | Frame Shift Ins (INS) | VAF 29/116 reads (25%) | called by mutect2, pindel, varscan2
- CEP192 | c.3325_3326del p.Q1109Efs*2 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel, varscan2
- GPR22 | c.262del p.D88Mfs*2 | Frame Shift Del (DEL) | VAF 28/120 reads (23%) | called by mutect2, pindel, varscan2
- HADHB | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- KIF26A | c.2861del p.P954Hfs*31 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- PARP6 | c.1639del p.Q547Rfs*15 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- SYT13 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- ADCK2 | c.783G>A p.R261= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV99301844; called by muse, mutect2, varscan2
- AGTR1 | c.885T>C p.N295= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1288771459, COSV100837166; called by muse, mutect2, varscan2
- AHR | c.1425T>C p.T475= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV99620196; called by muse, mutect2, varscan2
- AK5 | c.546T>A p.L182= (on ENST00000354567 / NM_174858.3; = p.L156= on NM_012093.4) | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as COSV100481568; called by muse, mutect2, varscan2
- AKAP13 | c.966G>A p.P322= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as rs371691695; called by muse, mutect2
- AKAP6 | c.381A>G p.T127= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs1255761374, COSV99804104; called by muse, mutect2, varscan2
- AKNAD1 | c.1362T>C p.G454= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs762139898, COSV100645827; called by muse, mutect2, varscan2
- ATP9B | c.1647G>A p.V549= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV100304131; called by muse, mutect2, varscan2
- BEND3 | c.1497C>T p.Y499= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs576232736, COSV64680297; called by muse, mutect2, varscan2
- C7 | c.2220G>T p.L740= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV100496518; called by muse, mutect2, varscan2
- CAD | c.1473C>T p.A491= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs770974703, COSV99255624; called by muse, mutect2, varscan2
- CHAD | c.127C>T p.L43= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99366315; called by muse, mutect2
- CHRNB4 | c.324G>A p.K108= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV55714573, COSV99929580; called by muse, mutect2, varscan2
- CNGB3 | c.222C>A p.S74= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV100182981; called by muse, mutect2, varscan2
- CRYGC | c.271C>A p.R91= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99965377; called by muse, mutect2, varscan2
- DDX25 | c.1110G>A p.G370= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV54989014, COSV99700098; called by muse, mutect2, varscan2
- DSCAML1 | c.1290G>T p.T430= (on ENST00000321322; = p.T370= on NM_020693.4) | Silent (SNP) | VAF 49/188 reads (26%) | catalogued as COSV100357077, COSV58389249; called by muse, mutect2, varscan2
- DSE | c.1920C>G p.P640= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as rs1347919128, COSV100528784; called by muse, mutect2, varscan2
- FAM47B | c.576C>G p.P192= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100264205, COSV100264590; called by muse, mutect2, varscan2
- FCRL5 | c.1233G>T p.L411= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100709285; called by muse, mutect2, varscan2
- HPX | c.219G>A p.E73= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV99793523; called by muse, mutect2
- IP6K3 | c.585G>A p.R195= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV99540125; called by muse, mutect2, varscan2
- IRAK4 | c.1365A>G p.Q455= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs767921421, COSV71210819, COSV71211012; called by muse, mutect2
- IRX1 | c.516G>C p.T172= | Silent (SNP) | VAF 63/156 reads (40%) | catalogued as COSV100116760; called by muse, mutect2, varscan2
- KCNK16 | c.603G>A p.E201= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as COSV100949314; called by muse, mutect2, varscan2
- KCTD16 | c.93C>A p.V31= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV101568878; called by muse, mutect2, varscan2
- KIFC2 | c.1557G>A p.R519= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs1354191936, COSV100023984; called by muse, mutect2, varscan2
- KPRP | c.1584C>G p.P528= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV100908790; called by muse, mutect2, varscan2
- L3MBTL1 | c.600G>T p.A200= (on ENST00000418998 / NM_001377303.1; = p.A110= on NM_015478.7) | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV100917327, COSV64232199; called by mutect2, varscan2
- MTM1 | c.1131C>T p.D377= | Silent (SNP) | VAF 40/61 reads (66%) | catalogued as rs1557414507, COSV100080658; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO7A | c.2914C>A p.R972= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as CM081714, COSV101289259, COSV68687619; called by muse, mutect2, varscan2
- NOS1 | c.3852G>C p.L1284= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV100501335; called by muse, mutect2, varscan2
- NOS1 | c.1056C>T p.D352= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs760416528, COSV57606762, COSV57611528; ClinVar: likely benign; called by muse, mutect2, varscan2
- NRXN3 | c.597G>A p.E199= | Silent (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- OBSCN | c.15006G>A p.E5002= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as COSV99483770; called by muse, mutect2, varscan2
- OR4Q3 | c.723C>T p.G241= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100057346, COSV59179754; called by muse, mutect2, varscan2
- OR52E2 | c.12C>A p.P4= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100384915; called by muse, mutect2, varscan2
- OR8K3 | c.589T>C p.L197= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs766405715, COSV100449883; called by muse, mutect2, varscan2
- PANX1 | c.1053G>A p.L351= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs756785063, COSV99921684, COSV99922011; called by muse, mutect2, varscan2
- PLEC | c.9213G>T p.T3071= (on ENST00000322810 / NM_201380.4; = p.T2961= on NM_000445.5) | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100518481; called by muse, mutect2
- PPFIA2 | c.60C>G p.S20= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100335053; called by muse, mutect2, varscan2
- PROKR2 | c.804C>A p.R268= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV99450606; called by muse, mutect2, varscan2
- PTPN13 | c.6525C>T p.N2175= (on ENST00000411767 / NM_080683.3; = p.N2156= on NM_006264.3) | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs765749481, COSV57412975; called by muse, mutect2, varscan2
- RITA1 | c.339G>A p.S113= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100232504; called by muse, mutect2, varscan2
- SERPING1 | c.1407G>A p.L469= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs751945279, COSV99558153, COSV99558175; called by muse, mutect2, varscan2
- TFAP2D | c.27C>T p.V9= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs772976908, COSV99147371; called by muse, mutect2, varscan2
- TNIK | c.567T>C p.I189= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as rs1216629625, COSV99459342; called by muse, mutect2
- TYRO3 | c.1347C>A p.I449= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV99778061; called by muse, mutect2, varscan2
- USH2A | c.11115A>T p.P3705= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV100241835, COSV56386185; called by muse, mutect2
- WFS1 | c.514C>T p.L172= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs371632935; called by muse, mutect2, varscan2
- ZFHX3 | c.6387C>A p.A2129= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99214481; called by muse, mutect2, varscan2
- ZNF136 | c.939T>C p.C313= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100678126; called by muse, mutect2, varscan2
- MYADM | chr19:53874370 C>T | 3'Flank (SNP) | VAF 11/74 reads (15%) | catalogued as rs757813539, COSV100425189; called by muse, mutect2, varscan2
- PCDH11X | c.3033+9C>T | Intron (SNP) | VAF 63/98 reads (64%) | catalogued as COSV100014775; called by muse, mutect2, varscan2
- VPS13B | c.4158-587C>A | Intron (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100663421; called by muse, mutect2, varscan2
- ZNF232 | c.-2C>G | 5'UTR (SNP) | VAF 7/33 reads (21%) | catalogued as rs766277515, COSV51503023; called by muse, mutect2, varscan2
